Somatic mutation profile of tumor specimen TCGA-BP-4995-01A (aliquot TCGA-BP-4995-01A-01D-1462-08) from TCGA case TCGA-BP-4995, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 68.0 years (24,850 days).
Specimen TCGA-BP-4995-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40616912-6bad-4601-8126-1ee2656da841.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4995-11A (Solid Tissue Normal), aliquot TCGA-BP-4995-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4be9d000-3f2d-4030-b50b-e57d4b706e83

The open-access MAF lists 47 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 13, Nonsense Mutation 6, In Frame Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC6A1 | c.1531G>A p.V511M | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs1064794981, COSV55117205; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2
- VHL | c.203C>A p.S68* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | hotspot (GDC flag); catalogued as rs869025617, CM003058, CM971566, COSV56542559, COSV56566398; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.307A>G p.R103G | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV54962203; called by muse, mutect2
- AHNAK2 | c.3748C>T p.Q1250* | Nonsense Mutation (SNP) | VAF 72/251 reads (29%) | catalogued as COSV60922752; called by muse, mutect2, varscan2
- ANK2 | c.8179C>T p.Q2727* | Nonsense Mutation (SNP) | VAF 39/138 reads (28%) | catalogued as COSV52175716; called by muse, mutect2, varscan2
- ANK3 | c.12961T>A p.C4321S (on ENST00000280772 / NM_001320874.2; = p.C945S on NM_001149.3) | Missense Mutation (SNP) | VAF 150/519 reads (29%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.054); catalogued as COSV55070614; called by muse, mutect2, varscan2
- CACNA1S | c.5177T>A p.L1726Q | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV62941878; called by muse, mutect2, varscan2
- CDC42BPA | c.3130G>T p.E1044* (on ENST00000334218 / NM_001366019.2; = p.E1031* on NM_003607.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/125 reads (21%) | catalogued as COSV62016132; called by muse, mutect2, varscan2
- CDH20 | c.2377G>A p.A793T | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs920131823, COSV53014103; called by muse, mutect2
- CHMP7 | c.1340A>C p.E447A | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV57533429; called by muse, mutect2, varscan2
- CYP3A7 | c.568G>T p.G190* | Nonsense Mutation (SNP) | VAF 61/221 reads (28%) | catalogued as COSV60482504; called by muse, mutect2, varscan2
- DDX5 | c.440_441+2del p.X147_splice | Splice Site (DEL) | VAF 70/278 reads (25%) | catalogued as rs782442161; called by mutect2, varscan2
- DLG5 | c.5645G>C p.R1882T | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV64948943; called by muse, mutect2, varscan2
- FAT3 | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 102/298 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.178); catalogued as rs968715356, COSV53146723; called by muse, mutect2, varscan2
- GRK6 | c.591T>A p.F197L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV62683554; called by muse, mutect2, varscan2
- LRP8 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.425); catalogued as rs149347479; called by muse, mutect2, varscan2
- LY9 | c.197C>G p.P66R | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV54436026; called by muse, mutect2, varscan2
- NCEH1 | c.244A>T p.I82F (on ENST00000538775; = p.I50F on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.276); catalogued as COSV56436331; called by muse, mutect2, varscan2
- PBRM1 | c.3143C>G p.P1048R (on ENST00000296302 / NM_001366071.2; = p.P1023R on NM_018313.5) | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56266459, COSV56304894; called by muse, mutect2, varscan2
- PIKFYVE | c.1541C>A p.S514Y | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV52245565, COSV52251033; called by muse, mutect2, varscan2
- PTGFR | c.413C>G p.T138R | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66115423, COSV66115919; called by muse, mutect2, varscan2
- RSAD2 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs751555584, COSV65908654; called by muse, mutect2, varscan2
- SLC8A3 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1185462859, COSV63520906, COSV63524309; called by muse, mutect2, varscan2
- SPAM1 | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.647); catalogued as COSV56146017; called by muse, mutect2, varscan2
- SVEP1 | c.3935A>G p.Q1312R | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.07); catalogued as rs760317465, COSV57031909, COSV57042296; called by muse, mutect2, varscan2
- TEC | c.1155G>T p.R385S | Missense Mutation (SNP) | VAF 85/232 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.872); catalogued as COSV67405630; called by muse, mutect2, varscan2
- TTN | c.56915A>T p.Q18972L (on ENST00000591111; = p.Q11548L on NM_003319.4) | Missense Mutation (SNP) | VAF 51/152 reads (34%) | PolyPhen benign (0.022); catalogued as COSV60206484; called by muse, mutect2, varscan2
- UBE2Q1 | c.1242G>A p.W414* | Nonsense Mutation (SNP) | VAF 68/262 reads (26%) | catalogued as COSV52726326; called by muse, mutect2, varscan2
- VEZT | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs373340086; called by muse, mutect2, varscan2
- VWA8 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.293); catalogued as rs1172769893, COSV55694188, COSV55701042; called by muse, mutect2, varscan2
- ZNF521 | c.3325G>A p.V1109I | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1259251891, COSV64129625; called by muse, mutect2, varscan2
- NBPF15 | c.1133T>G p.L378R | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, varscan2
- TLR2 | c.2123_2131del p.V708_S710del | In Frame Del (DEL) | VAF 58/281 reads (21%) | called by mutect2, pindel, varscan2
- ABCC1 | c.480C>T p.A160= | Silent (SNP) | VAF 45/205 reads (22%) | catalogued as COSV60690275; called by muse, mutect2, varscan2
- ACTN2 | c.2424C>A p.T808= | Silent (SNP) | VAF 46/167 reads (28%) | catalogued as COSV63972965, COSV63975200; called by muse, mutect2, varscan2
- COL6A6 | c.2697C>T p.F899= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV62031672; called by muse, mutect2, varscan2
- FANCF | c.513G>A p.L171= | Silent (SNP) | VAF 61/268 reads (23%) | catalogued as rs1353451639, COSV59416752; called by muse, mutect2, varscan2
- MAP1A | c.8121T>A p.A2707= | Silent (SNP) | VAF 48/157 reads (31%) | catalogued as COSV55811031; called by muse, mutect2, varscan2
- MTA2 | c.222G>C p.G74= | Silent (SNP) | VAF 61/231 reads (26%) | catalogued as COSV53873464; called by muse, mutect2, varscan2
- NMRAL1 | c.138G>A p.E46= | Silent (SNP) | VAF 184/430 reads (43%) | catalogued as COSV52060649; called by muse, mutect2, varscan2
- PCDHB7 | c.1575G>A p.Q525= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as COSV50794267; called by muse, mutect2, varscan2
- RREB1 | c.2934T>A p.S978= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV58561762; called by muse, mutect2, varscan2
- SLC7A2 | c.1104G>A p.A368= | Silent (SNP) | VAF 95/322 reads (30%) | catalogued as rs1134978; called by muse, mutect2, varscan2
- TMPRSS15 | c.735A>G p.K245= | Silent (SNP) | VAF 12/313 reads (4%) | catalogued as COSV53035198; called by muse, mutect2
- UGGT1 | c.2949G>T p.G983= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV52138951; called by muse, mutect2, varscan2
- ZNF438 | c.2178G>A p.L726= | Silent (SNP) | VAF 69/166 reads (42%) | catalogued as COSV59198371; called by muse, mutect2, varscan2
- DCHS2 | n.1871G>A | RNA (SNP) | VAF 18/53 reads (34%) | catalogued as rs1021249280, COSV59733500; called by muse, mutect2, varscan2
